Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A5RA, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A5RA-01A (Primary Tumor).

Tumor#

Normal#

ICD0-3
Astrocytoma, anaplastic 9401/3
Site Path Brain NOS C71.9
CSCE Brain, supratentorial C71.0
9/10 2/27/13

Microscopic Description:

The section of hippocampus shows infiltrating astrocytoma that is mildly to moderately cellular.

Sections demonstrate regions of markedly hypercellular high grade astrocytoma as well as areas of infiltrating tumor. In the latter, subpial condensation is seen.

Addendum Discussion:

Numerous MIB-1 reactive cells are scattered throughout the tumor. A labeling index of 17.2% is calculated.

Addendum Diagnosis:

Anaplastic Astrocytoma (WHO grade III)

MIB-1 Labeling Index= 17.2%

Review	hw 2/8/13	Yes	No

Source: NCI Genomic Data Commons file f4ce3a23-d8fb-467b-9d86-b4c8e5c703f4 (TCGA-HT-A5RA.4FF0C3AD-41E6-4814-9ED9-ED40691DE316.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).